Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A45K, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A45K-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (29 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, TWO FOCI (2.3 CM AND 0.4 CM), CONFINED TO THYROID.
- B. LARGEST FOCUS, LEFT LOBE (2.3 CM), ENCAPSULATED FOLLICULAR VARIANT WITH NO CAPSULAR OR ANGIOLYMPHATIC INVASION.
- C. PATHOLOGIC STAGE: pT2N0.
- D. ISTHMIC FOCUS (0.4 CM), MICROCARCINOMA WITH CYSTIC CHANGE, NO ANGIOLYMPHATIC INVASION (see comment).
- E. PATHOLOGIC STAGE: pT1aN0.
- F. THREE LYMPH NODES (ONE LEFT AND ONE RIGHT PERITHYROIDAL AND ONE ISTHMIC), NO TUMOR PRESENT (0/3).
- G. NODULAR THYROID HYPERPLASIA WITH CHRONIC LYMPHOCYTIC THYROIDITIS.

≥ 99% follicular variant per BS

PART 2: PARATHYROID, 1/2 LEFT SUPERIOR, EXCISION (153 MG) - ENLARGED HYPERCELLULAR PARATHYROID.

PART 3: PARATHYROID, 1/3 LEFT INFERIOR, EXCISION (14 MG) - SLIGHTLY ENLARGED MILDLY HYPERCELLULAR PARATHYROID.

PART 4: LYMPH NODES, CENTRAL COMPARTMENT, SELECTIVE DISSECTION -

- A. FIVE LYMPH NODES, NO TUMOR PRESENT (0/5).
- B. THYROID TISSUE WITH CHRONIC LYMPHOCYTIC THYROIDITIS.
- C. SPECIMEN ENTIRELY SUBMITTED FOR HISTOLOGIC EVALUATION.

PART 5: PARATHYROID, 1/4 RIGHT SUPERIOR, EXCISION (18 MG) - NORMOCYLLULAR PARATHYROID TISSUE.

ICD-0-3

carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS C73.9

in 9/29/12

COMMENT:

PART 1: The carcinoma is subcapsular, but shows no fibrosis. While technically there are two foci, these are different papillary carcinoma subtypes, and it can be argued that there is no intraglandular spread with respect to this microcarcinoma, which is cystic and of conventional histologic subtype.

PARTS 2, 3, AND 5: The intraoperative parathyroid hormone level decreased from 178 pg/ml to 12 pg/ml.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Left Lobe
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 2.3 cm
HISTOLOGIC TYPE: Papillary carcinoma, follicular variant, non-encapsulated
TNM DESCRIPTORS: m
PRIMARY TUMOR (pT): pT2
REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 8
Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Not identified
MARGINS: Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION: Not identified
ADDITIONAL PATHOLOGIC FINDINGS: Thyroiditis

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Isthmus
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 0.4 cm
HISTOLOGIC TYPE: Papillary carcinoma
TNM DESCRIPTORS: m
PRIMARY TUMOR (pT): pT1a
REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 8
Number of regional lymph nodes involved: 0

EXTRANODAL EXTENSION: Not identified
DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Not identified
MARGINS: Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION: Not identified
ADDITIONAL PATHOLOGIC FINDINGS: Thyroiditis

in 8/29/12

Source: NCI Genomic Data Commons file d734d37e-a4c4-4ab1-8f77-d02915508e93 (TCGA-BJ-A45K.5EA7DDF0-DC3F-4E56-B978-42A211C721DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).